Gene-level copy-number profile of tumor specimen TCGA-HC-A4ZV-01A from TCGA case TCGA-HC-A4ZV, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 56.5 years (20,634 days).
Specimen TCGA-HC-A4ZV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.49659412-6e8e-4709-800e-33b51308a282.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HC-A4ZV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1223e35d-b21f-4933-b9c7-80fcd3a3337f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 9,723; copy number 2: 41,639; copy number 3: 6,460; copy number 4: 1,575; copy number 5: 393; copy number 7: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HC-A4ZV-01A-11D-A26L-01): tumor purity 0.7, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:68,630,223–68,835,541, 9 genes (within-gene range 0–1): AC126773.1, AC126773.2, CDH3, AC126773.4, AC126773.5, HSPE1P5, CDH1, RNA5SP429, AC099314.1.
- chr16:72,112,157–72,822,781, 10 genes (within-gene range 0–1): PMFBP1, AC009075.1, LINC01572, AC009075.2, U6, AC004158.1, AC004943.2, RNU7-90P, KRT18P18, AC004943.3.
- chr16:72,805,998–73,006,141, 4 genes: AC004943.1, RNU7-71P, AC132068.1, AC002044.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 395 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:228,735,479–228,776,865, 2 genes, copy number 7: RHOU, AL078624.2.
- chr8:86,866,415–112,148,825, 391 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr8:112,446,575–112,539,317, 2 genes, copy number 5: AC024996.1, RPL30P16.

Autosomal genes at a single copy (total copy number 1): 8,048. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
